Gene-level copy-number profile of tumor specimen TCGA-50-5946-01A from TCGA case TCGA-50-5946, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,852 days).
Specimen TCGA-50-5946-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1db56321-02cf-4d03-b75e-ebb5ef05683c.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,875 have no estimate.
https://portal.gdc.cancer.gov/files/97eb2b2b-e566-4386-99d9-0cfa440e6064

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 461; copy number 2: 26,339; copy number 3: 21,227; copy number 4: 5,545; copy number 5: 1,176.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5946-01A-11D-1752-01): tumor purity 0.75, ploidy 2.63, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,176 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:549,197–56,632,727, 984 genes, copy number 5 (broad region; genes not listed).
- chr19:17,933,015–21,720,035, 192 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 461. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
